Somatic mutation profile of tumor specimen MMRF_2689_1_BM_CD138pos (aliquot MMRF_2689_1_BM_CD138pos_T1_KHS5U_L14259) from MMRF case MMRF_2689, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 62.3 years (22,741 days).
Specimen MMRF_2689_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fae419c2-05d1-42c0-a41f-21c57fda78c0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2689_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2689_1_PB_WBC_C3_KHS5U_L14260; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/39a4f787-29e3-4cea-8483-ad4222aeb600

The open-access MAF lists 108 somatic variants for this specimen: 52 protein-altering or splice-affecting, 12 silent, 44 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, 3'UTR 26, Silent 12, Intron 10, Frame Shift Del 4, RNA 3, 5'UTR 3, Splice Site 2, 3'Flank 2, Frame Shift Ins 2, In Frame Del 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 58/168 reads (35%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CADM2 | c.1015G>T p.A339S (on ENST00000407528 / NM_001167674.2; = p.A341S on NM_153184.4) | Missense Mutation (SNP) | VAF 137/669 reads (20%) | SIFT tolerated (0.7); PolyPhen benign (0.017); catalogued as COSV67390882; called by muse, mutect2, varscan2
- CPTP | c.463C>T p.R155C | Missense Mutation (SNP) | VAF 89/169 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375729538, COSV59562612; called by muse, mutect2, varscan2
- GAREM1 | c.2392G>A p.D798N (on ENST00000269209 / NM_001242409.2; = p.D797N on NM_022751.3) | Missense Mutation (SNP) | VAF 82/187 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.269); catalogued as rs1223919224, COSV99330319; called by muse, mutect2, varscan2
- IGHJ5 | c.47C>G p.S16* | Nonsense Mutation (SNP) | VAF 47/100 reads (47%) | catalogued as rs377330082; called by muse, varscan2
- IGHV1-69 | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 160/363 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.529); catalogued as rs575656143; called by muse, mutect2
- IGHV2-70 | c.290A>G p.N97S | Missense Mutation (SNP) | VAF 42/88 reads (48%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as rs769646259; called by muse, varscan2
- IGHV2-70 | c.100A>G p.T34A | Missense Mutation (SNP) | VAF 51/100 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.061); catalogued as rs570621406; called by muse, varscan2
- KCNF1 | c.895C>T p.R299C | Missense Mutation (SNP) | VAF 62/158 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV54464918; called by muse, mutect2, varscan2
- KLRF2 | c.46_48del p.C16del | In Frame Del (DEL) | VAF 69/157 reads (44%) | catalogued as rs529169373; called by mutect2, pindel, varscan2
- MYBPC3 | c.3770A>T p.N1257I | Missense Mutation (SNP) | VAF 60/119 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57029595; called by muse, mutect2, varscan2
- NFE2L2 | c.1496G>A p.R499Q | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.841); catalogued as rs752627827; called by muse, mutect2, varscan2
- NT5DC2 | c.1208C>T p.A403V | Missense Mutation (SNP) | VAF 51/186 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.104); catalogued as rs761501775; called by muse, mutect2, varscan2
- PEDS1 | c.644G>T p.R215L | Missense Mutation (SNP) | VAF 52/114 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV59014001; called by muse, mutect2, varscan2
- RADIL | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 56/128 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.335); catalogued as rs373936593; called by muse, mutect2
- RNPEP | c.1483C>T p.L495F | Missense Mutation (SNP) | VAF 37/64 reads (58%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.918); catalogued as COSV55243892; called by muse, mutect2, varscan2
- ZBTB20 | c.1365C>G p.S455R (on ENST00000474710 / NM_001164342.2; = p.S382R on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/394 reads (6%) | SIFT tolerated (0.54); PolyPhen benign (0.022); catalogued as rs184110076, COSV61859167; called by muse, mutect2
- ZNF185 | c.262C>T p.R88W | Missense Mutation (SNP) | VAF 131/139 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782556062; called by muse, mutect2, varscan2
- ANGPTL5 | c.558T>G p.D186E | Missense Mutation (SNP) | VAF 65/106 reads (61%) | SIFT tolerated (0.07); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- ASB4 | c.962C>T p.P321L | Missense Mutation (SNP) | VAF 51/152 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCDC27 | c.442+1G>T p.X148_splice | Splice Site (SNP) | VAF 8/99 reads (8%) | called by muse, mutect2
- CFAP221 | c.400T>C p.Y134H | Missense Mutation (SNP) | VAF 56/129 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.523); called by muse, mutect2, varscan2
- CFHR4 | c.681del p.V228Cfs*24 (on ENST00000367416 / NM_001201551.2; = p.V229Cfs*24 on NM_001201550.3) | Frame Shift Del (DEL) | VAF 39/112 reads (35%) | called by pindel, varscan2
- CKAP2L | c.1822+4C>T | Splice Region (SNP) | VAF 140/362 reads (39%) | called by muse, mutect2, varscan2
- COL4A4 | c.598T>A p.S200T | Missense Mutation (SNP) | VAF 42/147 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- COL6A6 | c.4586A>G p.E1529G | Missense Mutation (SNP) | VAF 71/376 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CTDSPL | c.191G>T p.S64I | Missense Mutation (SNP) | VAF 40/54 reads (74%) | SIFT deleterious (0.04); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- DLG5 | c.5740dup p.I1914Nfs*30 | Frame Shift Ins (INS) | VAF 127/379 reads (34%) | called by mutect2, pindel, varscan2
- EIF4A2 | c.622_623del p.I208Sfs*12 | Frame Shift Del (DEL) | VAF 19/84 reads (23%) | called by mutect2, pindel, varscan2
- FAT1 | c.12374A>G p.Q4125R | Missense Mutation (SNP) | VAF 66/161 reads (41%) | SIFT tolerated (0.51); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- GPR39 | c.302C>A p.T101K | Missense Mutation (SNP) | VAF 36/237 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.597); called by muse, mutect2, varscan2
- GRIN2A | c.3119A>T p.E1040V | Missense Mutation (SNP) | VAF 64/160 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- HLA-DPB1 | c.430T>G p.C144G | Missense Mutation (SNP) | VAF 161/272 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IER2 | c.646C>T p.L216F | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- IGHV2-70 | c.144_150del p.S49Vfs*5 | Frame Shift Del (DEL) | VAF 50/117 reads (43%) | called by pindel, varscan2
- IGHV3-30 | c.280T>G p.S94A | Missense Mutation (SNP) | VAF 118/800 reads (15%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.011); called by muse, mutect2
- INTS8 | c.344T>G p.L115R | Missense Mutation (SNP) | VAF 17/450 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ITIH2 | c.35T>C p.F12S | Missense Mutation (SNP) | VAF 8/229 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.202); called by muse, mutect2
- JUNB | c.322C>G p.Q108E | Missense Mutation (SNP) | VAF 119/239 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- MALRD1 | c.601G>A p.V201I | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT tolerated (0.65); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- MCOLN2 | c.710C>A p.S237Y | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.5); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MEX3D | c.397C>T p.P133S | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.39); called by muse, mutect2, varscan2
- NAB2 | c.380T>A p.L127H | Missense Mutation (SNP) | VAF 18/198 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.205); called by muse, mutect2
- PACC1 | c.1023A>T p.R341S | Missense Mutation (SNP) | VAF 117/298 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.098); called by muse, mutect2
- PARD3B | c.222+2T>C p.X74_splice | Splice Site (SNP) | VAF 98/211 reads (46%) | called by muse, mutect2, varscan2
- PATJ | c.3959+1del | Frame Shift Del (DEL) | VAF 20/132 reads (15%) | called by mutect2, pindel, varscan2
- PODXL | c.4_7dup p.C3Sfs*42 | Frame Shift Ins (INS) | VAF 69/145 reads (48%) | called by mutect2, pindel, varscan2
- PSEN1 | c.507_509del p.S170del | In Frame Del (DEL) | VAF 24/48 reads (50%) | called by pindel, varscan2
- RASIP1 | c.1625A>T p.E542V | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- RPL6 | c.395C>T p.P132L | Missense Mutation (SNP) | VAF 45/107 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- TRAPPC9 | c.736C>G p.L246V | Missense Mutation (SNP) | VAF 100/232 reads (43%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.865); called by muse, mutect2, varscan2
- USP14 | c.856C>G p.L286V | Missense Mutation (SNP) | VAF 36/73 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.377); called by muse, mutect2, varscan2
- ADAMTS18 | c.3066C>T p.A1022= | Silent (SNP) | VAF 65/149 reads (44%) | catalogued as rs374112306, COSV99273908; called by muse, mutect2, varscan2
- CD19 | c.1566A>T p.G522= (on ENST00000324662 / NM_001178098.2; = p.G521= on NM_001770.6) | Silent (SNP) | VAF 46/124 reads (37%) | called by muse, mutect2, varscan2
- CNOT1 | c.1131G>A p.V377= | Silent (SNP) | VAF 138/382 reads (36%) | called by muse, mutect2, varscan2
- FZD3 | c.1311A>T p.G437= | Silent (SNP) | VAF 96/265 reads (36%) | catalogued as rs1236277470; called by muse, mutect2, varscan2
- IGHV2-70D | c.126C>T p.T42= | Silent (SNP) | VAF 43/49 reads (88%) | catalogued as rs1473944355; called by muse, mutect2, varscan2
- KHNYN | c.1320T>C p.I440= | Silent (SNP) | VAF 11/286 reads (4%) | called by muse, mutect2
- MYO6 | c.1470G>A p.K490= | Silent (SNP) | VAF 18/52 reads (35%) | called by muse, mutect2, varscan2
- MYT1 | c.2715C>T p.S905= | Silent (SNP) | VAF 46/106 reads (43%) | catalogued as rs758487002; called by muse, mutect2, varscan2
- PLAUR | c.807C>T p.C269= | Silent (SNP) | VAF 6/149 reads (4%) | called by muse, mutect2
- RIPK4 | c.2400G>A p.E800= (on ENST00000352483; = p.E752= on NM_020639.3) | Silent (SNP) | VAF 49/135 reads (36%) | called by muse, mutect2, varscan2
- SLC28A1 | c.1773C>T p.Y591= | Silent (SNP) | VAF 18/495 reads (4%) | catalogued as COSV99723618; called by muse, mutect2
- TRPM2 | c.723C>T p.V241= | Silent (SNP) | VAF 18/161 reads (11%) | called by muse, mutect2
- AC104057.1 | n.418G>A | RNA (SNP) | VAF 9/206 reads (4%) | called by muse, mutect2
- AKIRIN1 | c.*348A>G | 3'UTR (SNP) | VAF 35/95 reads (37%) | catalogued as rs969705126; called by muse, mutect2, varscan2
- C9orf106 | n.396C>T | RNA (SNP) | VAF 70/156 reads (45%) | called by muse, mutect2, varscan2
- CNTNAP2 | c.*3797G>A | 3'UTR (SNP) | VAF 21/39 reads (54%) | catalogued as rs957393593; called by muse, mutect2, varscan2
- COL1A2 | c.*215T>A | 3'UTR (SNP) | VAF 24/88 reads (27%) | called by muse, mutect2, varscan2
- EDRF1 | c.2815-109C>T | Intron (SNP) | VAF 15/31 reads (48%) | called by muse, mutect2, varscan2
- EMC8 | c.*704G>A | 3'UTR (SNP) | VAF 79/211 reads (37%) | catalogued as rs1284836992; called by muse, mutect2, varscan2
- FAM126B | c.626+63T>A | Intron (SNP) | VAF 18/38 reads (47%) | called by muse, mutect2, varscan2
- FAM71D | c.1190-276G>A | Intron (SNP) | VAF 41/104 reads (39%) | called by muse, mutect2, varscan2
- FOXP2 | c.*1528A>T | 3'UTR (SNP) | VAF 23/131 reads (18%) | called by muse, mutect2, varscan2
- FRMD3 | c.1070+942A>T | Intron (SNP) | VAF 22/436 reads (5%) | called by muse, mutect2
- FRMD3 | c.1070+941G>T | Intron (SNP) | VAF 22/430 reads (5%) | catalogued as COSV58460949; called by muse, mutect2
- GRIP2 | c.781+148T>A | Intron (SNP) | VAF 5/61 reads (8%) | called by muse, mutect2
- IGLL5 | c.-41G>A | 5'UTR (SNP) | VAF 43/55 reads (78%) | catalogued as rs1331166632, COSV104440291; called by muse, varscan2
- KLHDC2 | c.-242C>T | 5'UTR (SNP) | VAF 11/23 reads (48%) | called by muse, mutect2, varscan2
- LAMB3 | c.*211T>C | 3'UTR (SNP) | VAF 7/50 reads (14%) | called by muse, mutect2, varscan2
- LDLRAP1 | c.*1544C>T | 3'UTR (SNP) | VAF 44/101 reads (44%) | catalogued as rs898491981; called by muse, mutect2, varscan2
- LINC01749 | n.168G>T | RNA (SNP) | VAF 35/61 reads (57%) | called by muse, mutect2, varscan2
- MEIS2 | c.*967A>T | 3'UTR (SNP) | VAF 39/126 reads (31%) | called by muse, mutect2, varscan2
- MID1IP1 | c.*78T>C | 3'UTR (SNP) | VAF 18/24 reads (75%) | called by mutect2, varscan2
- MYOCD | c.2059-1566G>A | Intron (SNP) | VAF 73/138 reads (53%) | called by muse, mutect2, varscan2
- NFATC2 | c.*51C>T | 3'UTR (SNP) | VAF 50/125 reads (40%) | called by muse, mutect2, varscan2
- NPY1R | c.*846A>T | 3'UTR (SNP) | VAF 21/51 reads (41%) | catalogued as COSV56717012; called by muse, mutect2, varscan2
- NSUN3 | c.*1177C>G | 3'UTR (SNP) | VAF 46/137 reads (34%) | called by muse, mutect2, varscan2
- PAK5 | c.*1210G>A | 3'UTR (SNP) | VAF 72/192 reads (38%) | called by muse, mutect2, varscan2
- PALM2AKAP2 | chr9:110171675 C>T | 3'Flank (SNP) | VAF 77/189 reads (41%) | called by muse, mutect2, varscan2
- PARPBP | c.*525T>G | 3'UTR (SNP) | VAF 26/55 reads (47%) | called by muse, mutect2, varscan2
- PAX1 | c.*569del | 3'UTR (DEL) | VAF 35/71 reads (49%) | catalogued as rs914765827; called by mutect2, varscan2
- PCMTD1 | c.*2610T>G | 3'UTR (SNP) | VAF 55/284 reads (19%) | catalogued as rs1393875342; called by muse, mutect2, varscan2
- PHF14 | c.*11T>C | 3'UTR (SNP) | VAF 324/759 reads (43%) | called by muse, mutect2, varscan2
- PHF24 | c.*3504T>C | 3'UTR (SNP) | VAF 12/188 reads (6%) | called by muse, mutect2
- PKP4 | c.*470A>G | 3'UTR (SNP) | VAF 38/73 reads (52%) | called by muse, mutect2, varscan2
- PRDM16-DT | n.1019+11C>A | Intron (SNP) | VAF 19/59 reads (32%) | catalogued as rs554643586; called by muse, mutect2, varscan2
- SERP1 | c.*2315C>T | 3'UTR (SNP) | VAF 40/157 reads (25%) | called by muse, mutect2, varscan2
- SIPA1L1 | c.-108G>T | 5'UTR (SNP) | VAF 32/144 reads (22%) | called by muse, mutect2
- SIVA1 | c.471-24C>G | Intron (SNP) | VAF 40/251 reads (16%) | called by muse, mutect2, varscan2
- STEAP4 | c.*5213G>C | 3'UTR (SNP) | VAF 13/35 reads (37%) | called by muse, mutect2, varscan2
- SYNPR | c.*507G>A | 3'UTR (SNP) | VAF 7/79 reads (9%) | catalogued as rs1250194341; called by muse, mutect2
- SYT14 | chr1:210163253 T>A | 3'Flank (SNP) | VAF 22/65 reads (34%) | called by muse, mutect2, varscan2
- TIA1 | c.*1297A>C | 3'UTR (SNP) | VAF 28/68 reads (41%) | called by muse, mutect2, varscan2
- TMEM107 | c.*815A>G | 3'UTR (SNP) | VAF 31/65 reads (48%) | catalogued as rs1209632210; called by muse, mutect2
- TTPAL | c.*1559T>A | 3'UTR (SNP) | VAF 4/22 reads (18%) | catalogued as rs867362639, COSV52828261; called by muse, varscan2
- UNC5C | c.*793A>T | 3'UTR (SNP) | VAF 16/45 reads (36%) | catalogued as rs1560709118; called by mutect2, varscan2
- WDR97 | c.1844-32G>A | Intron (SNP) | VAF 8/219 reads (4%) | catalogued as rs1025602833, COSV100075588; called by muse, mutect2
